Gene-level copy-number profile of specimen HCM-CSHL-0323-C20-85A from HCMI case HCM-CSHL-0323-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.2 years (19,788 days).
Specimen HCM-CSHL-0323-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9ffe171d-b2de-411f-92ab-b37e22c676fa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0323-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/365c0283-c081-4187-a58c-116ad591d191

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 438; copy number 1: 2,468; copy number 2: 35,677; copy number 3: 14,075; copy number 4: 6,159; copy number 5: 79; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 82 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–268,655, 1 gene, copy number 6: AP006222.2.
- chr8:41,435,298–46,793,064, 81 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,468. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
